Somatic mutation profile of tumor specimen TCGA-EM-A3FL-01A (aliquot TCGA-EM-A3FL-01A-11D-A21A-08) from TCGA case TCGA-EM-A3FL, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 63.5 years (23,183 days).
Specimen TCGA-EM-A3FL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f15a8a1-39be-4f43-8082-275a55244cb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3FL-10A (Blood Derived Normal), aliquot TCGA-EM-A3FL-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa6f5938-cb6f-4126-8438-10bb59c86354

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM5A | c.3484A>C p.K1162Q | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV66991225; called by muse, mutect2, varscan2
- NEDD4 | c.1417A>G p.K473E | Missense Mutation (SNP) | VAF 5/107 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as COSV59060087; called by muse, mutect2
- TPTE2 | c.1266G>T p.K422N (on ENST00000400230 / NM_199254.2; = p.K345N on NM_130785.3) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as rs372777846; called by muse, mutect2
- TULP2 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); catalogued as rs771301026, COSV55477365; called by muse, mutect2, varscan2
- MKLN1 | c.21C>T p.V7= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs142689824, COSV61760335; called by muse, mutect2
- SLC44A3 | c.186C>T p.L62= (on ENST00000271227 / NM_001114106.3; = p.L14= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/151 reads (6%) | catalogued as rs1458054490, COSV54728878; called by muse, mutect2
- STX17 | c.333A>G p.E111= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV52282954; called by muse, mutect2, varscan2
- TCP1 | c.633C>T p.I211= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as COSV58457995; called by muse, mutect2, varscan2
